Somatic mutation profile of cancer-model specimen HCM-CSHL-0078-C25-85M (3D Organoid; aliquot HCM-CSHL-0078-C25-85M-01D-A78M-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1391c3a9-ed9a-4552-83a8-9c30507f9cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0078-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0078-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58b1518b-df84-4331-a8ca-5bf748d5594b

The open-access MAF lists 136 somatic variants for this specimen: 93 protein-altering or splice-affecting, 29 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 29, RNA 4, Frame Shift Del 4, Intron 3, 5'UTR 2, 3'UTR 2, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 364/365 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.411T>G p.F137L | Missense Mutation (SNP) | VAF 90/536 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs559187706; called by muse, mutect2, varscan2
- ADNP | c.3062G>C p.G1021A | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1237911024; called by muse, mutect2, varscan2
- ANGPTL2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52218961; called by muse, mutect2
- BCAS3 | c.1969G>A p.V657I (on ENST00000390652 / NM_001353144.2; = p.V642I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.093); catalogued as rs766648044; called by muse, varscan2
- C2orf50 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101059477; called by muse, mutect2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CDC5L | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 145/214 reads (68%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs756396867; called by muse, mutect2, varscan2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2
- DOK2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766198984; called by muse, mutect2, varscan2
- ENAH | c.435-1G>C p.X145_splice | Splice Site (SNP) | VAF 32/84 reads (38%) | catalogued as rs752410405; called by mutect2, varscan2
- ERBB4 | c.2046G>C p.K682N | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53593480; called by muse, mutect2, varscan2
- FAT2 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55815910; called by muse, mutect2, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- GABRD | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs1259972227; called by muse, mutect2, varscan2
- GRIA2 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as COSV52394837, COSV52401238; called by muse, mutect2, varscan2
- HEXD | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1220811941, COSV60063615; called by muse, mutect2
- HJV | c.1240C>T p.L414F (on ENST00000336751 / NM_213653.4; = p.L301F on NM_145277.5) | Missense Mutation (SNP) | VAF 66/1202 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1553769357; called by muse, mutect2
- HOXD12 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1216506512, COSV101184276; called by muse, mutect2, varscan2
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 175/1276 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- KLF12 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs774840041; called by mutect2, varscan2
- LAMA5 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 318/645 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53362723; called by muse, mutect2, varscan2
- LAMC2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51456248; called by muse, mutect2, varscan2
- LPA | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 153/529 reads (29%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1170862921, COSV60303792; called by muse, mutect2, varscan2
- MECR | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs749351701; called by muse, mutect2, varscan2
- MINDY4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 65/402 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370104814; called by muse, mutect2, varscan2
- MTOR | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs376836258, COSV63869206; called by mutect2, varscan2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by mutect2, varscan2
- PALM | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372771354; called by muse, mutect2, varscan2
- POLR1E | c.1046G>A p.R349Q (on ENST00000377792 / NM_001282766.1; = p.R287Q on NM_022490.4) | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs745330508, COSV66773064; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 160/417 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- SPN | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs968049985, COSV64070098; called by muse, mutect2, varscan2
- SSTR4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372339309; called by muse, mutect2, varscan2
- SYNRG | c.2138A>G p.D713G | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as rs759722631; called by muse, mutect2
- TAL1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs759386045; called by muse, mutect2, varscan2
- TBC1D1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV54722841; called by muse, mutect2, varscan2
- TMEM91 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as rs1032654429, COSV99652565; called by muse, mutect2, varscan2
- TPO | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1396786379, COSV61095304; called by muse, mutect2, varscan2
- TRIP12 | c.3807G>C p.Q1269H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.948); catalogued as rs745404222; called by muse, mutect2, varscan2
- USP6NL | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs781289702, COSV53209782; called by muse, mutect2, varscan2
- VEPH1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 137/227 reads (60%) | catalogued as COSV62882192; called by muse, mutect2, varscan2
- VSTM2A | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs199714481, COSV56493317; called by muse, mutect2, varscan2
- ZFHX4 | c.6683C>T p.S2228F | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99256741; called by muse, mutect2, varscan2
- ZNF516 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296532817; called by muse, mutect2, varscan2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 144/211 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- ADGRL3 | c.4396A>G p.S1466G (on ENST00000506720 / NM_001322402.2; = p.S1355G on NM_015236.6) | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARFGEF3 | c.2435G>C p.S812T | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 315/493 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEACAM18 | c.968G>C p.C323S | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD1 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COG3 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DDX31 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNASE1L1 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNASE2 | c.141_142del p.G48Afs*49 | Frame Shift Del (DEL) | VAF 94/439 reads (21%) | called by pindel, varscan2
- FAM169A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FLG | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 184/1180 reads (16%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FOXC1 | c.18dup p.V7Rfs*76 | Frame Shift Ins (INS) | VAF 36/49 reads (73%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRM1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 18/547 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- HECA | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 89/170 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IPO5 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM5C | c.1503_1519del p.W501Cfs*10 | Frame Shift Del (DEL) | VAF 74/83 reads (89%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRRC1 | c.28T>A p.C10S | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MUC6 | c.6589_6590del p.L2197Ffs*12 | Frame Shift Del (DEL) | VAF 58/173 reads (34%) | called by pindel, varscan2
- NEB | c.16955A>G p.Y5652C | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP4 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- OR51C1P | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PDE6B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHF12 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PPHLN1 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PTPN13 | c.7224C>A p.C2408* (on ENST00000411767 / NM_080683.3; = p.C2389* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 75/170 reads (44%) | called by muse, mutect2, varscan2
- RBM26 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIOK2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SAMD8 | c.204A>T p.L68F | Missense Mutation (SNP) | VAF 102/156 reads (65%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SCN2A | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 97/513 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SLC5A8 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 41/50 reads (82%) | called by pindel, varscan2
- SLC6A5 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2
- SNRPA1 | c.355A>T p.S119C | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.127); called by muse, mutect2
- TANC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 191/318 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TLN1 | c.4240G>C p.A1414P | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM237 | c.874G>T p.D292Y (on ENST00000409883 / NM_001044385.3; = p.D284Y on NM_152388.4) | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNKS | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.31510C>G p.P10504A (on ENST00000591111; = p.P9577A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/211 reads (16%) | PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- WDR62 | c.77del p.P26Rfs*51 | Frame Shift Del (DEL) | VAF 57/222 reads (26%) | called by mutect2, pindel, varscan2
- WNK2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 354/561 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX2 | c.6059G>C p.S2020T | Missense Mutation (SNP) | VAF 97/167 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF202 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ZNF423 | c.3835C>G p.Q1279E (on ENST00000563137 / NM_001379286.1; = p.Q1271E on NM_015069.4) | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ZNF436 | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF551 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1377C>T p.P459= | Silent (SNP) | VAF 160/2390 reads (7%) | catalogued as rs779949072, COSV55000365; called by muse, mutect2
- ATG4B | c.222C>T p.C74= | Silent (SNP) | VAF 62/410 reads (15%) | called by muse, mutect2, varscan2
- C1QTNF8 | c.414C>T p.F138= | Silent (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- CLSTN2 | c.696G>T p.L232= | Silent (SNP) | VAF 141/219 reads (64%) | called by muse, mutect2, varscan2
- CYP26B1 | c.1131G>A p.Q377= | Silent (SNP) | VAF 101/509 reads (20%) | called by muse, mutect2, varscan2
- DPF2 | c.432C>T p.G144= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as COSV52888870; called by muse, mutect2, varscan2
- ELOA2 | c.1182G>A p.K394= | Silent (SNP) | VAF 89/321 reads (28%) | called by muse, mutect2, varscan2
- EVC2 | c.3615C>T p.S1205= | Silent (SNP) | VAF 179/398 reads (45%) | called by muse, mutect2, varscan2
- FIZ1 | c.693G>A p.P231= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- FLG | c.7242C>T p.F2414= | Silent (SNP) | VAF 152/1192 reads (13%) | called by muse, mutect2, varscan2
- IRX3 | c.1473C>T p.A491= | Silent (SNP) | VAF 147/240 reads (61%) | called by muse, mutect2, varscan2
- KRT37 | c.807G>T p.L269= | Silent (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- MED23 | c.1296C>A p.L432= | Silent (SNP) | VAF 59/299 reads (20%) | called by muse, mutect2, varscan2
- NEB | c.10305G>A p.P3435= | Silent (SNP) | VAF 114/495 reads (23%) | catalogued as rs528974814, COSV99415147; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.1749C>T p.P583= | Silent (SNP) | VAF 47/47 reads (100%) | called by muse, mutect2, varscan2
- NF1 | c.8109G>A p.L2703= (on ENST00000358273 / NM_001042492.3; = p.L2682= on NM_000267.3) | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as rs1397862679; called by muse, mutect2, varscan2
- NPC1L1 | c.927C>T p.P309= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs1017546573, COSV56922987; called by muse, mutect2, varscan2
- OBSCN | c.5016G>A p.V1672= | Silent (SNP) | VAF 154/332 reads (46%) | catalogued as COSV99486630; called by muse, mutect2, varscan2
- PGM5 | c.1566C>T p.Y522= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as rs782534536, COSV67166795; called by muse, mutect2, varscan2
- PIEZO1 | c.4098G>A p.Q1366= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1168119514; called by muse, mutect2, varscan2
- RBM25 | c.462G>A p.E154= | Silent (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1770T>C p.I590= | Silent (SNP) | VAF 32/253 reads (13%) | catalogued as rs202135271, COSV62885368; called by muse, mutect2, varscan2
- SPATA31E1 | c.1080C>T p.D360= | Silent (SNP) | VAF 104/368 reads (28%) | catalogued as rs199568188, COSV57789870; called by muse, mutect2, varscan2
- TIE1 | c.2826T>C p.A942= | Silent (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- TMEM121B | c.891C>T p.G297= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TNRC18 | c.5952G>A p.A1984= | Silent (SNP) | VAF 110/376 reads (29%) | catalogued as rs778246311; called by muse, mutect2
- TSPAN5 | c.606T>C p.Y202= | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as rs760214816; called by muse, mutect2, varscan2
- VPS13D | c.4890G>A p.Q1630= | Silent (SNP) | VAF 61/116 reads (53%) | called by muse, mutect2, varscan2
- ZNF556 | c.15C>A p.V5= | Silent (SNP) | VAF 58/196 reads (30%) | called by muse, mutect2, varscan2
- AC006305.1 | n.825A>G | RNA (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- ACBD4 | chr17:45143641 G>A | 3'Flank (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- C8orf87 | n.87C>T | RNA (SNP) | VAF 36/329 reads (11%) | catalogued as rs771548195; called by muse, mutect2, varscan2
- DSTN | c.-84G>T | 5'UTR (SNP) | VAF 64/271 reads (24%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+325T>C | Intron (SNP) | VAF 117/472 reads (25%) | called by muse, mutect2, varscan2
- FAM161A | c.*1279T>C | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- GPNMB | c.541+30C>A | Intron (SNP) | VAF 183/340 reads (54%) | called by muse, mutect2, varscan2
- HAUS7 | chrX:153470957 T>A | 5'Flank (SNP) | VAF 91/91 reads (100%) | called by muse, mutect2, varscan2
- LINC00602 | n.592C>A | RNA (SNP) | VAF 202/460 reads (44%) | catalogued as rs969920362; called by muse, mutect2, varscan2
- LINC01193 | n.1330C>A | RNA (SNP) | VAF 42/331 reads (13%) | called by muse, mutect2, varscan2
- PADI4 | c.-2C>T | 5'UTR (SNP) | VAF 68/132 reads (52%) | catalogued as rs200461292; called by muse, mutect2, varscan2
- PYCARD | c.275-76del | Intron (DEL) | VAF 56/187 reads (30%) | called by mutect2, pindel, varscan2
- RNU7-174P | chr8:80559425 C>T | 5'Flank (SNP) | VAF 146/508 reads (29%) | catalogued as rs1159050845; called by muse, mutect2, varscan2
- VMP1 | c.*1440C>A | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
